Somatic mutation profile of tumor specimen HCM-BROD-0041-C64-86A (aliquot HCM-BROD-0041-C64-86A-01D-A937-36) from HCMI case HCM-BROD-0041-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 7.3 years (2,655 days).
Specimen HCM-BROD-0041-C64-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66ea6b6b-3ae9-404a-bbe3-5a43506078e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0041-C64-10A (Blood Derived Normal), aliquot HCM-BROD-0041-C64-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a466bd1-3166-483d-a5c0-3adff210d509

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 534/880 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1998G>T p.K666N | Missense Mutation (SNP) | VAF 220/436 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 517/520 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DDAH2 | c.536G>C p.G179A | Missense Mutation (SNP) | VAF 262/583 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.286); catalogued as COSV65384647; called by muse, mutect2, varscan2
- ZNF84 | c.2021A>G p.Q674R | Missense Mutation (SNP) | VAF 190/469 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs923589702; called by muse, mutect2, varscan2
- ARHGAP23 | c.3868G>A p.E1290K | Missense Mutation (SNP) | VAF 47/767 reads (6%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- ASH1L | c.1255A>G p.K419E | Missense Mutation (SNP) | VAF 27/1089 reads (2%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.332); called by muse, mutect2
- DOCK2 | c.1792G>T p.D598Y | Missense Mutation (SNP) | VAF 26/498 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MARS1 | c.2177A>T p.K726M | Missense Mutation (SNP) | VAF 129/296 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- OSBPL3 | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 74/196 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- PPP3CA | c.959C>A p.A320E | Missense Mutation (SNP) | VAF 113/113 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, varscan2
- RSPH6A | c.1346T>C p.I449T | Missense Mutation (SNP) | VAF 213/495 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TULP4 | c.3979C>T p.P1327S | Missense Mutation (SNP) | VAF 215/458 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XK | c.333A>T p.K111N | Missense Mutation (SNP) | VAF 281/572 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- AP1S2 | c.162G>A p.L54= | Silent (SNP) | VAF 31/419 reads (7%) | called by muse, mutect2
- HNRNPA1 | c.1101C>T p.G367= (on ENST00000340913 / NM_031157.4; = p.G315= on NM_002136.4) | Silent (SNP) | VAF 131/354 reads (37%) | catalogued as rs760229094, COSV52937492; called by muse, varscan2
- REXO1 | c.2484G>A p.E828= | Silent (SNP) | VAF 15/348 reads (4%) | called by muse, mutect2
- ZFHX4 | c.8415G>A p.S2805= | Silent (SNP) | VAF 226/456 reads (50%) | catalogued as rs368980001; called by muse, mutect2, varscan2
